Surgical pathology report (de-identified scan), TCGA case TCGA-XE-AANX, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-XE-AANX-01A (Primary Tumor).

[page 1 of 3]
Acct#:

Ord #=

SURGICAL PATHOL

Modifiers:

RESULTED

Collect D/T=

(1 of 1)

Surgical Pathology Report

Specimen(s) Received
Right testicular mass

Clinical History
Not stated.

COLE ICD-03
Mixed embryonal carcinoma +
teratoma 9081/3
path
Mixed germ cell tumor 9085/3
Site Testis NOS C62.9
JP 3/31/14

Gross Description

Right testicular mass: Received in formalin is a 42-gram specimen including right testis 4.5 x 3.5 x 2 cm, right spermatic cord 9 cms in length x 2 cm in diameter, epididymis 4.5 x 1 x 1 cm. Cut section reveals intraparenchymal well-circumscribed, lobulated, fleshy mass at the superior pole of the testis close to the head of epididymis, measuring 3.1 x 2.5 x 2.0 cms. The firm, ovoid tumor mass has a fleshy appearance with areas of hemorrhage and does not appear to penetrate the tunica albuginea. The spermatic cord section is sectioned at several levels and appears grossly unremarkable. Representative sections are submitted in nine cassettes. Cassette summary as follows:

- 1 cord and resection margin
- 2 spermatic cord, mid, and peritesticular sections
- 3 tumor with normal testis
- 4-7 tumor with adjacent epididymis
- 8 tumor and normal testis
- 9 representative section of normal testis

Date of Dictation:

Date of Dictation:

Gross Description By:

Microscopic Description

[page 2 of 3]
SURGICAL PATHOL

-(Continued)

Acct#:

Performed.

Final Pathologic Diagnosis

Right testicular mass:

-Mixed germ cell tumor 75% embryonal carcinoma, 20% teratoma with immature glandular and mesenchymal components (see comment), 5% yolk sac tumor.

-Maximum dimension: 3.1 cm.

-Tumor extends into the tunica albuginea but does not involve the tunica vaginalis.

-Lymphovascular invasion is identified.

-Epididymis is uninvolved.

-Embryonal carcinoma present within the spermatic cord in lymphovascular channels; no direct invasion of cord identified.

-The spermatic cord margin is negative for carcinoma.

Pathologic Stage: pT2NXMX (Stage IB)

Comment: The sarcomatous stroma is focal and scant (no nodule formation).

Attending Pathologist:

***Electronically Signed Out By

Patient Name:

Case #:

Med. Rec. #:

Location:

Date Collected:

Pw TSS dx discrepancy form,
TLGA tumor is: embryonal 80%
Mature teratoma 20%

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Embryonal Carcinoma 75%, Teratoma with immature glandular and mesenchymal components 20%, Yolk Sac Tumor 5%	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Embryonal Carcinoma 80%, Teratoma (mature) 20%	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	histologic heterogeneity characteristic of mixed germ cell tumors	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 9f25dda3-1843-470b-a14e-eedeb861eb2c (TCGA-XE-AANX-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).